Somatic mutation profile of tumor specimen 0DK1WA from CCDI case PBBXTU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.1 years (4,425 days).
Specimen 0DK1WA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7485beab-f12b-4ca7-99dc-98d928463984.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK1WL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10626934-3a6b-4d8a-ab4d-f4ae3bf280b2

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 5, Intron 2, 3'UTR 1, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRINP2 | c.1719G>T p.Q573H | Missense Mutation (SNP) | VAF 112/298 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV64177551, COSV64178140; called by muse, varscan2
- FKBP9 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 314/863 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752507806; called by muse, varscan2
- DZIP1L | c.1614A>G p.S538= | Splice Region (SNP) | VAF 203/495 reads (41%) | called by muse, varscan2
- EOMES | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 330/809 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KDM6A | c.3497G>C p.W1166S | Missense Mutation (SNP) | VAF 571/696 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KMT2C | c.9373dup p.R3125Kfs*16 | Frame Shift Ins (INS) | VAF 299/890 reads (34%) | called by pindel, varscan2
- MYMX | c.67C>A p.R23S | Missense Mutation (SNP) | VAF 313/791 reads (40%) | SIFT deleterious, low confidence (0); called by muse, varscan2
- ZKSCAN4 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 252/633 reads (40%) | called by muse, varscan2
- AKAP11 | c.3003A>C p.S1001= | Silent (SNP) | VAF 398/850 reads (47%) | called by muse, varscan2
- EIF4ENIF1 | c.1959G>A p.V653= | Silent (SNP) | VAF 370/832 reads (44%) | called by muse, varscan2
- KHNYN | c.1446T>G p.P482= | Silent (SNP) | VAF 212/492 reads (43%) | called by muse, varscan2
- TSPAN11 | c.486C>T p.A162= | Silent (SNP) | VAF 264/679 reads (39%) | catalogued as rs138636959; called by muse, varscan2
- ZNF700 | c.1257G>A p.E419= | Silent (SNP) | VAF 103/240 reads (43%) | catalogued as COSV54312649; called by muse, varscan2
- ERCC6 | c.1397+7381A>G | Intron (SNP) | VAF 407/920 reads (44%) | catalogued as rs767400753; called by muse, varscan2
- PCYT2 | c.903+11G>A | Intron (SNP) | VAF 166/666 reads (25%) | catalogued as rs540809800, COSV58712143; called by muse, varscan2
- ROBO1 | c.*74C>T | 3'UTR (SNP) | VAF 252/557 reads (45%) | catalogued as rs1028896657; called by muse, varscan2
